Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1ME, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1ME-01A (Primary Tumor).

1CB-0-3
Adenocarcinoma, NOS 8140/3
Site: Cervix, NOS C53.9 2/24/11
JW

SURGICAL PATHOLOGY REPORT - CONSULT

Patient Name: [REDACTED]
Address: [REDACTED] Service: Inside/Outside
Location: [REDACTED] Accession #: [REDACTED]
Received: [REDACTED]
Gender: F MRN: [REDACTED]
DOB: [REDACTED] Hospital #: [REDACTED]
Patient Type: [REDACTED]
Physician(s): [REDACTED] M.D.

DIAGNOSIS

UTERUS, CERVIX, BIOPSY
- ADENOCARCINOMA, WELL-DIFFERENTIATED (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment

Histologic section of the cervical biopsy shows a well-differentiated adenocarcinoma. The predominant pattern of this tumor is villoglandular papillary adenocarcinoma with fibrovascular cores of variable lengths lined by neoplastic epithelium that exhibits predominantly intestinal-type differentiation. Dispersed throughout the villoglandular adenocarcinoma are areas showing complex cribriform architecture. These cribriform areas represent about 10-15% of lesional tissue. Although stromal invasion is not definitively identified, there is essentially no normal stroma present within the biopsy tissue to exclude an invasive component. Dr. [REDACTED] has reviewed this case and concurs.

History

The patient is a [REDACTED] year old woman with a history of atypical glandular cells on Pap smear. Operative procedure: Cervical biopsy.

Material(s) Received

Received is one slide labeled [REDACTED]. It is derived from a cervical biopsy performed on [REDACTED]. The material originates from [REDACTED].

Physician Copy -

Source: NCI Genomic Data Commons file f2d45ed6-5f7e-4378-9908-9096a3349d7c (TCGA-C5-A1ME.00322045-7A7F-44D1-8381-94F027200227.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).